Somatic mutation profile of tumor specimen RC-B65B-TBP1-A (aliquot RC-B65B-TBP1-A-1-0-D-A93N-47) from RC case RC-B65B, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 79.7 years (29,093 days).
Specimen RC-B65B-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b0fa861-b7e3-4d59-b6ef-6d672aa94645.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65B-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65B-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a15e88c-4190-4b60-b593-45e5dd65b28b

The open-access MAF lists 128 somatic variants for this specimen: 85 protein-altering or splice-affecting, 38 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 38, Intron 4, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPS6KA3 | c.1894C>T p.R632* | Nonsense Mutation (SNP) | VAF 19/21 reads (90%) | catalogued as rs1085307639; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOB | c.3125C>T p.A1042V | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs61741467; called by muse, mutect2, varscan2
- BAX | c.199G>C p.G67R | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV53170407; called by muse, mutect2, varscan2
- CD109 | c.3603A>T p.E1201D | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99755110; called by muse, mutect2, varscan2
- CD163 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757801947, COSV63130962; called by muse, mutect2, varscan2
- CD3E | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62345856; called by muse, mutect2, varscan2
- CR1 | c.3781T>A p.F1261I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.763); catalogued as rs1482459919; called by muse, mutect2, varscan2
- DDC | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1316356550; called by muse, mutect2, varscan2
- DNAH6 | c.11101G>A p.E3701K | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52857880; called by muse, mutect2, varscan2
- EP400 | c.4370C>T p.T1457M | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as rs746082327; called by muse, mutect2, varscan2
- EPHA7 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV65190919; called by muse, mutect2, varscan2
- EXOC3L1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs182198466; called by muse, mutect2, varscan2
- GLIS1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs934965650, COSV56554517; called by muse, mutect2, varscan2
- HLA-E | c.1005T>C p.G335= | Splice Region (SNP) | VAF 63/161 reads (39%) | catalogued as rs775947602; called by muse, mutect2, varscan2
- IRAG1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs766892331, COSV70210172; called by muse, mutect2, varscan2
- KDM6A | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs1453322733, COSV65037342, COSV65037876; called by muse, mutect2, varscan2
- KIAA2012 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480565111; called by muse, mutect2, varscan2
- NRAS | c.216G>C p.M72I | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.562); catalogued as COSV54762820; called by muse, mutect2, varscan2
- OR13D1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs768764389, COSV99079600; called by muse, mutect2, varscan2
- OTOG | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs779427684; called by muse, mutect2, varscan2
- PCDHA12 | c.1768G>A p.V590M | Missense Mutation (SNP) | VAF 107/199 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); catalogued as rs1481558429, COSV100249844, COSV56481676; called by muse, mutect2, varscan2
- PIEZO2 | c.6949C>T p.R2317* | Nonsense Mutation (SNP) | VAF 28/101 reads (28%) | catalogued as rs1329879893, COSV53290118, COSV99555074; called by muse, mutect2, varscan2
- PKNOX2 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53549789; called by muse, mutect2, varscan2
- PPFIA4 | c.2644C>T p.R882W (on ENST00000447715; = p.R883W on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753391903; called by muse, mutect2, varscan2
- RPA4 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs183526208; called by muse, mutect2, varscan2
- SEL1L2 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs770442031, COSV53157989; called by muse, mutect2, varscan2
- SH3BP4 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs373202308; called by muse, mutect2, varscan2
- ST8SIA6 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373503230; called by muse, mutect2, varscan2
- STK36 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs759453372, COSV99831538; called by muse, mutect2, varscan2
- TAF6L | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs143375984; called by muse, mutect2, varscan2
- TENM4 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as rs1248881354, COSV53619871, COSV99576043; called by muse, mutect2, varscan2
- TRAM1L1 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs771632784; called by muse, mutect2, varscan2
- TUSC3 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs751767095, COSV65879020; called by muse, mutect2, varscan2
- VAV1 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); catalogued as COSV58379897; called by muse, mutect2, varscan2
- ZNF469 | c.8266C>T p.R2756* (on ENST00000437464; = p.R2784* on NM_001367624.2) | Nonsense Mutation (SNP) | VAF 68/151 reads (45%) | catalogued as rs1172315984; called by muse, mutect2, varscan2
- ZNF804A | c.820A>C p.K274Q | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs145899824, COSV56472601; called by muse, mutect2
- ABCA8 | c.886T>A p.L296M | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- AHNAK2 | c.11854G>C p.G3952R | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- ARHGAP40 | c.1510A>G p.M504V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C16orf71 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CCND3 | c.787_797del p.S263Afs*57 | Frame Shift Del (DEL) | VAF 54/106 reads (51%) | called by mutect2, pindel, varscan2
- CDH13 | c.1687C>G p.P563A | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD2 | c.1778T>C p.I593T | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CTCF | c.1068C>G p.C356W | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOT1L | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- EIF2S2 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT tolerated (0.86); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- FCGR2C | c.243T>G p.I81M | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, varscan2
- GABRA6 | c.374T>A p.I125N | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GABRA6 | c.375T>G p.I125M | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GFI1 | c.1010dup p.R338Sfs*28 | Frame Shift Ins (INS) | VAF 32/84 reads (38%) | called by mutect2, pindel, varscan2
- GYPB | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HYOU1 | c.636C>G p.S212R | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- IRX4 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.082); called by mutect2, varscan2
- ITPR1 | c.5041G>A p.E1681K (on ENST00000354582; = p.E1666K on NM_002222.7) | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM1A | c.2229C>G p.P743= | Splice Region (SNP) | VAF 45/85 reads (53%) | called by muse, mutect2, varscan2
- KIAA1549L | c.40G>A p.G14S (on ENST00000321505; = p.G311S on NM_012194.3) | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- KIF18A | c.1605T>G p.D535E | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL4 | c.695C>A p.A232E | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NBEA | c.7134T>G p.H2378Q | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NKX2-5 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, varscan2
- NOL4L | c.209A>T p.N70I | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OR52A1 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PLCL1 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLXNA4 | c.2959G>A p.V987M | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- POF1B | c.1456C>G p.H486D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRKD2 | c.1681C>A p.Q561K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PSD | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABEP1 | c.1829T>G p.L610R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- S100A6 | c.101T>A p.L34Q | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SERPINB3 | c.535G>C p.A179P | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SETD1B | c.5459A>G p.N1820S | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SFSWAP | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, varscan2
- SIN3A | c.1086_1092del p.A363Sfs*25 | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | called by mutect2, pindel, varscan2
- SIRPB2 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC12A2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, varscan2
- SPTBN5 | c.7150G>A p.E2384K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TBC1D24 | c.1415C>T p.S472F (on ENST00000646147 / NM_001199107.2; = p.S466F on NM_020705.3) | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TET2 | c.5987G>A p.G1996E | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRBV6-1 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- TTC37 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ZFP36 | c.389G>A p.C130Y (on ENST00000594442; = p.C124Y on NM_003407.5) | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFR | c.862_901del p.K288Lfs*19 | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | called by mutect2, varscan2
- ZNF135 | c.1139A>C p.K380T (on ENST00000313434 / NM_001289401.2; = p.K392T on NM_003436.4) | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF608 | c.4008G>A p.M1336I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNHIT1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL3 | c.2955C>T p.C985= (on ENST00000506720 / NM_001322402.2; = p.C917= on NM_015236.6) | Silent (SNP) | VAF 45/127 reads (35%) | called by muse, mutect2, varscan2
- AHNAK2 | c.10923C>A p.P3641= | Silent (SNP) | VAF 110/226 reads (49%) | called by muse, varscan2
- ANK3 | c.9567C>T p.L3189= | Silent (SNP) | VAF 60/130 reads (46%) | catalogued as rs929137423; called by muse, mutect2, varscan2
- ANXA10 | c.318C>T p.G106= | Silent (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- CAST | c.6C>T p.S2= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs1415450362; called by muse, mutect2, varscan2
- CEACAM16 | c.525C>T p.L175= | Silent (SNP) | VAF 56/150 reads (37%) | catalogued as COSV101312763; called by muse, mutect2, varscan2
- CNTN5 | c.87T>C p.T29= | Silent (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.426T>A p.S142= | Silent (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- CTNNBL1 | c.999C>T p.G333= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as rs373840043; called by muse, mutect2, varscan2
- DAPK3 | c.900G>A p.T300= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs1354633913, COSV56664298; called by muse, mutect2, varscan2
- DMPK | c.1320C>T p.P440= | Silent (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- DOLPP1 | c.615C>T p.I205= | Silent (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- DPYSL5 | c.309C>T p.P103= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as rs757282159; called by muse, mutect2, varscan2
- DSG4 | c.2013T>A p.P671= | Silent (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- EIF2S2 | c.366C>A p.G122= | Silent (SNP) | VAF 51/82 reads (62%) | called by muse, mutect2, varscan2
- ENTHD1 | c.222C>T p.S74= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as COSV57322502; called by muse, mutect2, varscan2
- IQCA1L | c.1650C>T p.S550= | Silent (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2, varscan2
- KIAA2012 | c.1743G>A p.E581= | Silent (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- LCA5 | c.688T>C p.L230= | Silent (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- LRRC4B | c.1584G>A p.G528= | Silent (SNP) | VAF 72/147 reads (49%) | catalogued as rs769009111; called by muse, mutect2, varscan2
- NCOA7 | c.1149T>G p.G383= | Silent (SNP) | VAF 67/155 reads (43%) | called by muse, mutect2
- NOX4 | c.1695A>T p.S565= | Silent (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- OR10J1 | c.474G>A p.T158= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as rs149860482, COSV71128517; called by muse, varscan2
- OR8K5 | c.243G>T p.V81= | Silent (SNP) | VAF 55/123 reads (45%) | catalogued as COSV57888305; called by muse, mutect2, varscan2
- OTOF | c.5505G>A p.A1835= (on ENST00000272371 / NM_194248.3; = p.A1068= on NM_004802.4) | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as rs368190044; ClinVar: likely benign; called by muse, mutect2, varscan2
- PFKFB3 | c.1656C>T p.P552= | Silent (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- PNPLA3 | c.681C>T p.V227= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs556789077, COSV53381029; called by muse, mutect2, varscan2
- SCART1 | c.2367C>T p.R789= | Silent (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- SFSWAP | c.573C>T p.P191= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV99906271; called by muse, varscan2
- SPDYE5 | c.777G>A p.E259= | Silent (SNP) | VAF 84/169 reads (50%) | called by muse, varscan2
- SRMS | c.1443C>T p.H481= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs186038529, COSV53918286; called by muse, mutect2, varscan2
- TBC1D9 | c.1296C>T p.S432= | Silent (SNP) | VAF 44/128 reads (34%) | called by muse, mutect2, varscan2
- TBX3 | c.1173C>T p.D391= (on ENST00000257566 / NM_016569.4; = p.D371= on NM_005996.4) | Silent (SNP) | VAF 29/168 reads (17%) | catalogued as rs762528344, COSV57472932; called by muse, mutect2, varscan2
- TRAF3 | c.1437T>G p.R479= | Silent (SNP) | VAF 46/113 reads (41%) | called by muse, mutect2, varscan2
- TRIL | c.1239C>T p.S413= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- ZFP28 | c.30C>T p.R10= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs763343777; called by muse, mutect2, varscan2
- ZNF804B | c.2763C>T p.T921= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV60818887, COSV60826727; called by muse, mutect2, varscan2
- ZNF865 | c.1047G>A p.P349= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as rs532802546; called by muse, mutect2, varscan2
- AC074389.2 | n.213C>T | RNA (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- CPED1 | c.540+3855C>T | Intron (SNP) | VAF 47/114 reads (41%) | called by muse, varscan2
- RARB | c.179-32327G>A | Intron (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1523A>T | Intron (SNP) | VAF 64/145 reads (44%) | called by muse, mutect2, varscan2
- TSNARE1 | c.1446+3326C>T | Intron (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
